Gene-level copy-number profile of tumor specimen TCGA-D3-A3MU-06A from TCGA case TCGA-D3-A3MU, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 54.3 years (19,830 days).
Specimen TCGA-D3-A3MU-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-SKCM.407a61c9-24ef-4572-a740-b0bb91b96517.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-D3-A3MU-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/273d08e2-dd77-48bf-80db-6c34ed214268

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 6,169; copy number 2: 35,756; copy number 3: 13,297; copy number 4: 1,602; copy number 5: 2,983; copy number 6: 13.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-D3-A3MU-06A-11D-A219-01): tumor purity 0.84, ploidy 2.41, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 2,996 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:6,532,891–6,533,200, 1 gene, copy number 5: AC027334.1.
- chr5:8,444,949–8,685,816, 13 genes, copy number 6: AC091965.4, MIR4458HG, AC091965.2, AC091965.5, MIR4458, AC091953.1, AC091953.3, AC091953.5, MTND6P2, MTCYBP37, AC091953.2, AC091953.6, AC091953.4.
- chr5:16,473,038–16,936,288, 5 genes, copy number 5 (within-gene range 3–5): RETREG1, AC024588.1, AC022113.1, Y_RNA, MYO10.
- chr5:32,226,994–32,312,987, 1 gene, copy number 5 (within-gene range 3–5): MTMR12.
- chr5:32,309,662–35,048,135, 48 genes, copy number 5: RNU6-378P, ZFR, MIR579, AC074134.1, SUB1, LINC02061, AC008766.1, NPR3, AC025459.1, AC010343.3, LINC02120, AC034223.1, AC034223.2, AC010343.2, AC010343.1, LINC02160, AC025472.1, AC034231.1, TARS1, TOMM40P3, AC034232.1, ADAMTS12, RNU6-923P, RXFP3, SLC45A2, AC139783.2, AMACR, C1QTNF3-AMACR, AC139783.1, C1QTNF3, AC139792.2, AC139792.3, AC139792.1, AC138409.2, AC138409.1, AC138409.3, AC138853.1, AC025754.2, RAI14, AC025754.1, AC026801.2, TTC23L, AC026801.1, RPL21P54, RAD1, BRIX1, DNAJC21, AGXT2.
- chr5:35,081,223–35,081,992, 1 gene, copy number 5: AC010368.1.
- chr5:37,379,285–37,953,827, 6 genes, copy number 5 (within-gene range 4–5): WDR70, KCTD9P5, RNU6-1190P, RNU6-484P, GDNF-AS1, GDNF.
- chr7:70,972–152,936,981, 2,921 genes, copy number 5 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 3,782. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
